Somatic mutation profile of tumor specimen TCGA-HW-7486-01A (aliquot TCGA-HW-7486-01A-11D-2024-08) from TCGA case TCGA-HW-7486, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 37.1 years (13,546 days).
Specimen TCGA-HW-7486-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 477196a1-f803-4e1b-940c-f6cc3c7b7dea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HW-7486-10A (Blood Derived Normal), aliquot TCGA-HW-7486-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf32c785-7827-4b7d-804b-754ab194c4d7

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- COL21A1 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as rs749746863, COSV55161650; called by muse, mutect2, varscan2
- ENOSF1 | c.245A>G p.Y82C (on ENST00000340116 / NM_001354066.2; = p.Y34C on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179155706, COSV51892387; called by muse, mutect2
- NRROS | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as rs1356037628, COSV60745797; called by muse, mutect2
- PCDHGC5 | c.803A>G p.D268G | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52751306; called by muse, mutect2, varscan2
- SIX2 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV57390835; called by muse, mutect2
- SKI | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1057524781, COSV66013443; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXK1 | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 2/20 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.407); called by muse, mutect2
- ALDH8A1 | c.1146G>A p.K382= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as rs1477763000, COSV55641682; called by muse, mutect2, varscan2
- CASR | c.2547G>A p.Q849= (on ENST00000490131; = p.Q926= on NM_000388.4) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1423302864, COSV56137245; called by muse, mutect2, varscan2
- EMC4 | c.126C>G p.L42= | Silent (SNP) | VAF 51/147 reads (35%) | catalogued as rs769169415, COSV50784692; called by muse, mutect2, varscan2
- FYB2 | c.2148T>C p.I716= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV58584922; called by muse, mutect2, varscan2
- GSK3B | c.270C>T p.D90= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as COSV51775303; called by muse, mutect2, varscan2
- XRCC5 | c.471T>C p.C157= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV67536142; called by muse, mutect2
- TTN | c.10361-4849A>G | Intron (SNP) | VAF 35/122 reads (29%) | called by muse, mutect2, varscan2
